Somatic mutation profile of tumor specimen TCGA-CV-7410-01A (aliquot TCGA-CV-7410-01A-21D-2078-08) from TCGA case TCGA-CV-7410, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Larynx, NOS; AJCC pathologic stage: Stage III; Tumor grade: GX; Age at diagnosis: 61.1 years (22,302 days).
Specimen TCGA-CV-7410-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ff10ab8f-fdf1-42ae-9bcd-c0b681be5fb6.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CV-7410-10A (Blood Derived Normal), aliquot TCGA-CV-7410-10A-01D-2078-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7a64d7fa-c32a-4784-b549-dfa90c5af0ae

The open-access MAF lists 47 somatic variants for this specimen: 37 protein-altering or splice-affecting, 8 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 31, Silent 8, Nonsense Mutation 3, Intron 2, Splice Site 1, Frame Shift Ins 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- RHOA | c.118G>C p.E40Q | Missense Mutation (SNP) | VAF 10/100 reads (10%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen benign (0.41); catalogued as rs1057519951, COSV69041613, COSV69042111, COSV69043712; ClinVar: likely pathogenic; called by muse, mutect2
- ARHGEF11 | c.4123G>A p.D1375N | Missense Mutation (SNP) | VAF 3/48 reads (6%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.001); catalogued as rs1382037589; called by muse, mutect2
- ATP11C | c.1535G>T p.G512V | Missense Mutation (SNP) | VAF 4/48 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100557698; called by muse, mutect2
- BRPF3 | c.1708C>T p.R570W | Missense Mutation (SNP) | VAF 5/32 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs761546570, COSV60206960; called by muse, mutect2, varscan2
- CCDC171 | c.3661G>A p.E1221K | Missense Mutation (SNP) | VAF 6/55 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.654); catalogued as COSV101048483, COSV66244680; called by muse, mutect2, varscan2
- CEP57L1 | c.1054G>T p.E352* | Nonsense Mutation (SNP) | VAF 8/78 reads (10%) | catalogued as COSV100425775; called by muse, mutect2, varscan2
- COL19A1 | c.305T>C p.V102A | Missense Mutation (SNP) | VAF 16/116 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.024); catalogued as COSV100505929; called by muse, mutect2, varscan2
- COL27A1 | c.3048G>A p.M1016I | Missense Mutation (SNP) | VAF 10/106 reads (9%) | SIFT tolerated (0.17); PolyPhen benign (0.007); catalogued as COSV100620888; called by muse, mutect2
- CTBS | c.851C>A p.A284D | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV99759679; called by muse, mutect2
- DHRS7C | c.235G>C p.D79H | Missense Mutation (SNP) | VAF 7/64 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.944); catalogued as COSV100364634, COSV57651918; called by muse, mutect2, varscan2
- IGHMBP2 | c.1777G>A p.E593K | Missense Mutation (SNP) | VAF 12/154 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV99661974; called by muse, mutect2
- IQGAP1 | c.4111G>A p.V1371M | Missense Mutation (SNP) | VAF 7/77 reads (9%) | SIFT tolerated (0.07); PolyPhen benign (0.043); catalogued as rs181919733, COSV99184939; called by muse, mutect2
- IRAK3 | c.1694C>G p.S565* | Nonsense Mutation (SNP) | VAF 12/126 reads (10%) | catalogued as COSV99706076; called by muse, mutect2, varscan2
- ITPRID1 | c.2473G>A p.E825K | Missense Mutation (SNP) | VAF 8/82 reads (10%) | SIFT tolerated (0.41); PolyPhen benign (0.037); catalogued as COSV100086126; called by muse, mutect2
- KIF2C | c.1294G>A p.V432M | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV64763913, COSV64765288; called by muse, mutect2
- MCF2 | c.939G>T p.E313D | Missense Mutation (SNP) | VAF 6/86 reads (7%) | SIFT tolerated (0.08); PolyPhen benign (0.033); catalogued as COSV100644663; called by muse, mutect2
- MCM2 | c.1609G>A p.E537K | Missense Mutation (SNP) | VAF 9/132 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV99413004, COSV99413437; called by muse, mutect2
- MMEL1 | c.559C>G p.Q187E | Missense Mutation (SNP) | VAF 4/47 reads (9%) | SIFT tolerated (0.66); PolyPhen benign (0.013); catalogued as COSV99983576; called by muse, mutect2
- MXRA5 | c.2518G>T p.E840* | Nonsense Mutation (SNP) | VAF 8/79 reads (10%) | catalogued as COSV54230987, COSV99476431; called by muse, mutect2
- OR2L8 | c.76T>G p.F26V | Missense Mutation (SNP) | VAF 14/214 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as COSV61727783; called by muse, mutect2
- OR5D18 | c.150C>G p.I50M | Missense Mutation (SNP) | VAF 16/147 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.495); catalogued as COSV100450629; called by muse, mutect2, varscan2
- PCDH9 | c.1210G>A p.E404K | Missense Mutation (SNP) | VAF 7/111 reads (6%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.696); catalogued as COSV100119593, COSV60583607; called by muse, mutect2
- PEAK1 | c.4558G>C p.E1520Q | Missense Mutation (SNP) | VAF 6/57 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100432794; called by muse, mutect2
- POU4F1 | c.1204T>G p.W402G | Missense Mutation (SNP) | VAF 5/85 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV101020516; called by muse, mutect2
- PRIMPOL | c.592G>C p.D198H | Missense Mutation (SNP) | VAF 7/109 reads (6%) | SIFT tolerated (0.47); PolyPhen benign (0); catalogued as COSV100153095; called by muse, mutect2
- PRRC2A | c.2468G>A p.S823N | Missense Mutation (SNP) | VAF 8/84 reads (10%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.778); catalogued as COSV101051103; called by muse, mutect2, varscan2
- SEMA3E | c.2068A>T p.R690W | Missense Mutation (SNP) | VAF 6/88 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.199); catalogued as COSV57078912; called by muse, mutect2
- SF3B3 | c.2271C>G p.I757M | Missense Mutation (SNP) | VAF 6/68 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV100209748; called by muse, mutect2
- SIM1 | c.1139C>T p.S380L | Missense Mutation (SNP) | VAF 4/55 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.111); catalogued as rs1334153580, COSV99492209; called by muse, mutect2
- SMR3B | c.227C>A p.P76H | Missense Mutation (SNP) | VAF 7/86 reads (8%) | PolyPhen benign (0.043); catalogued as COSV100513354; called by muse, mutect2
- STING1 | c.952G>A p.A318T | Missense Mutation (SNP) | VAF 5/33 reads (15%) | SIFT tolerated (0.39); PolyPhen benign (0.011); catalogued as COSV100423436; called by muse, mutect2
- TTN | c.7595-2A>G p.X2532_splice (on ENST00000591111; = p.X2486_splice on NM_003319.4) | Splice Site (SNP) | VAF 6/48 reads (13%) | catalogued as COSV100604277; called by muse, mutect2, varscan2
- UTP11 | c.371A>T p.H124L | Missense Mutation (SNP) | VAF 4/69 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100884885; called by muse, mutect2
- ZNF536 | c.824G>A p.R275H | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62832714; called by muse, mutect2, varscan2
- CDH10 | c.2299G>C p.E767Q | Missense Mutation (SNP) | VAF 8/147 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.752); called by muse, mutect2
- RBM12B | c.2303_2304dup p.E769Qfs*119 | Frame Shift Ins (INS) | VAF 14/85 reads (16%) | called by mutect2, varscan2
- TP53 | c.518_524del p.V173Afs*72 | Frame Shift Del (DEL) | VAF 4/47 reads (9%) | called by mutect2, pindel*, varscan2*
- MYO16 | c.1386A>T p.S462= | Silent (SNP) | VAF 9/142 reads (6%) | catalogued as COSV99193780; called by muse, mutect2
- RNF213 | c.1056G>A p.V352= | Silent (SNP) | VAF 3/27 reads (11%) | catalogued as COSV100173336; called by muse, mutect2
- SLC40A1 | c.627G>A p.S209= | Silent (SNP) | VAF 4/63 reads (6%) | catalogued as rs1010890004, COSV53724259; called by muse, mutect2
- SPP2 | c.504C>T p.L168= | Silent (SNP) | VAF 6/96 reads (6%) | catalogued as COSV99394504; called by muse, mutect2
- SPTA1 | c.984G>A p.E328= | Silent (SNP) | VAF 7/173 reads (4%) | catalogued as COSV63756164; called by muse, mutect2
- TAS2R60 | c.402G>A p.K134= | Silent (SNP) | VAF 12/182 reads (7%) | catalogued as rs919299515, COSV100223514, COSV60331517; called by muse, mutect2
- TTN | c.8412G>C p.V2804= (on ENST00000591111; = p.V2758= on NM_003319.4) | Silent (SNP) | VAF 6/110 reads (5%) | catalogued as COSV100604272, COSV104415034; called by muse, mutect2
- XYLT1 | c.2340G>A p.V780= | Silent (SNP) | VAF 4/72 reads (6%) | catalogued as COSV99761174; called by muse, mutect2
- MRPL3 | c.630-7843G>A | Intron (SNP) | VAF 4/36 reads (11%) | catalogued as COSV99394723, COSV99394861; called by muse, mutect2
- TSR1 | c.1770+158G>C | Intron (SNP) | VAF 10/81 reads (12%) | catalogued as COSV100026940, COSV100027060; called by muse, mutect2, varscan2
